Surgical pathology report (de-identified scan), TCGA case TCGA-ZR-A9CJ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZR-A9CJ-01B (Primary Tumor).

[page 1 of 3]
Nature of Specimen(s)

1. Oesophagectomy
2. Splenic lymph node
3. Subcarinal lymph node
4. Right crus lymph node

MALE

Clinical Information Supplied

Oesophagectomy for oesophageal cancer (specimen)

Macro Report

Length of oesophagus: 47mm
Length of stomach (maximum): 50x125mm
Width of tumour: Circumferential.
Length of tumour: 42mm
Tumour edge to nearest proximal margin: 19mm
Macroscopic type of tumour: Flat, circumferential.
Length (macroscopic) Barrett's mucosa: Nil identified.

Comment:

Part of the oesophagus and stomach with the above measurements. There is a circumferential tumour measuring 42mm in length lying 19mm from the proximal resection margin and 10mm from the distal resection margin. The majority of the tumour lies in the oesophagus but it does extend through the gastro-oesophageal junction and approximately 5-10mm of tumour is visible within the stomach. On sectioning, the tumour does not obviously involve the circumferential margin which has been inked blue. Obvious metastatic nodes are visible. Blocks taken: 1A proximal resection margin; 1B distal resection margin; 1C-G representative sections of tumour; 1H-P lymph nodes; 1Q-T megablocks showing whole circumference of tumour. Tissue remains.

ICD-O-3

Adenocarcinoma NOS 8140/3

Page 1 of 3

Site Oesophagus, distal third

path Oesophagus NOS Q15.9

Q15.9/14

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 2 of 3]
2. Fibrofatty tissue measuring 30x32x5mm. The tissue is bisected and no obvious nodes are identified. The tissue is all processed in 2 cassettes.

3. Two pieces of pale tissue measuring 10x8x4mm and 13x7x5mm. Both pieces are processed intact in separate cassettes.

4. Fibrofatty tissue measuring 32x8x9mm. Tissue is bisected and all processed in 2 cassettes.

Micro Report

1. Type of tumour:

Adenocarcinoma: Yes.

Differentiation by predominant area:
Moderately: Yes.

Depth of invasion: T3 invasion beyond muscularis propria.

Serosal involvement: No.

Tumour Regression Grade (Mandard criteria)
5. Absence of regressive changes

Proximal margin:

Barrett's: Yes.

Circumferential margin

Involvement (<1mm): No.

Distance of carcinoma to nearest circumferential margin: 4.1mm

Distal margin features: Normal.

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 3 of 3]
Other features:

Vascular invasion: Yes.
Barrett's metaplasia: Yes.
Adjacent to tumour: No.

Lymph nodes

Number examined: 24
Number positive: 12

Distant metastases N/A.

Comments:

Sections show poorly to moderately differentiated adenocarcinoma with lymphovascular and perineural invasion. Tumour extends beyond the muscularis propria into the adventitia but does not extend to the circumferential margin. Tumour is present in 12 out of the 18 nodes identified.

2-4. Sections of the splenic, subcarinal and right cross lymph nodes show no evidence of invasive malignancy.

Pathological staging: TNM 6 T3 N1 Mx
TNM 7 T3 N3 Mx

Signature of Pathologist(s)

Page 3 of 3

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

Source: NCI Genomic Data Commons file 4c18373f-5b13-453a-a3bb-891beee19be2 (TCGA-ZR-A9CJ.28EE3969-4B2A-46C6-974A-E49C13DC7CEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).